Gene-level copy-number profile of tumor specimen TCGA-N5-A4RD-01A from TCGA case TCGA-N5-A4RD, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IVB; Age at diagnosis: 69.6 years (25,413 days).
Specimen TCGA-N5-A4RD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.f3533e94-f784-4ab8-a62b-06bce367d282.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A4RD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c506ac54-5e19-421d-924f-ce6ac62efb4f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 2: 12,180; copy number 3: 8,932; copy number 4: 19,457; copy number 5: 14,990; copy number 6: 2,709; copy number 7: 1,100; copy number 9: 2; copy number 10: 223; copy number 12: 17; copy number 13: 22; copy number 14: 7; copy number 17: 15; copy number 20: 149.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A4RD-01A-11D-A28Q-01): tumor purity 0.91, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,751,512–87,994,695, 8 genes (within-gene range 0–2): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 68 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:123,843,036–124,033,301, 5 genes, copy number 10: PIGFP2, LHX2, AC006450.3, AC006450.1, AC006450.2.
- chr13:84,520,103–84,563,236, 3 genes, copy number 13: MTND4P1, MTND5P3, LINC00333.
- chr13:85,363,601–85,544,570, 1 gene, copy number 14: LINC00351.
- chr13:90,060,247–91,354,579, 19 genes, copy number 13: LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.
- chr13:100,338,982–100,675,093, 8 genes, copy number 9–14: AL353697.1, PCCA-AS1, GGACT, AL356966.1, AL136526.1, RPS26P47, TMTC4, COX5BP6.
- chr13:108,335,354–109,915,420, 15 genes, copy number 17: AL138694.1, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10.
- chr13:109,988,097–110,129,136, 1 gene, copy number 12 (within-gene range 2–12): AL390755.1.
- chr13:110,053,285–110,763,133, 16 genes, copy number 12: LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
